Somatic mutation profile of tumor specimen 0E1FGM from CCDI case PBCVLZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1FGM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e3796bc-f360-4647-b019-3439ef461b57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1FGT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38752cce-9b2c-4af2-b1f9-6d017804a432

The open-access MAF lists 16 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 6, Missense Mutation 6, Silent 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SSMEM1 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 40/590 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as rs373212095; called by muse, mutect2
- CDC6 | c.891G>T p.L297F | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC1I2 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 154/378 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- HOXB13 | c.22A>C p.T8P | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.284); called by muse, mutect2
- MYH8 | c.3568G>T p.A1190S | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2
- ZC2HC1B | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CGN | c.3226C>A p.R1076= | Silent (SNP) | VAF 39/384 reads (10%) | called by muse, mutect2
- MUC16 | c.6180C>A p.P2060= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV101201638; called by muse, mutect2, varscan2
- AZIN2 | c.1244+88T>C | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- DOK5 | c.*12A>C | 3'UTR (SNP) | VAF 38/494 reads (8%) | called by muse, mutect2
- DSC1 | c.2239-79C>T | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- IL1RAP | c.1051+60G>T | Intron (SNP) | VAF 67/229 reads (29%) | called by muse, mutect2, varscan2
- MOSPD2 | c.1090-73dup | Intron (INS) | VAF 15/59 reads (25%) | called by mutect2, varscan2
- MUC2 | chr11:1099598 G>A | 5'Flank (SNP) | VAF 4/32 reads (13%) | catalogued as rs765993810; called by mutect2, varscan2
- SAR1B | c.179-47A>T | Intron (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- VILL | c.2205+48C>A | Intron (SNP) | VAF 27/34 reads (79%) | called by muse, varscan2
